Gene-level copy-number profile of tumor specimen TCGA-G4-6306-01A from TCGA case TCGA-G4-6306, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; Age at diagnosis: 71.6 years (26,163 days).
Specimen TCGA-G4-6306-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.e29fdcee-031c-4244-9bea-a0b82e0d44f9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-G4-6306-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/09592bba-44c4-4edc-9d88-3709ef3ba621

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,455; copy number 2: 44,653; copy number 3: 8,677; copy number 5: 1,391; copy number 6: 2,643.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-G4-6306-01A-11D-1770-01): tumor purity 0.74, ploidy 2.33, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,034 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:41,509,593–145,066,685, 1,606 genes, copy number 6 (broad region; genes not listed).
- chr13:18,467,172–114,337,626, 1,391 genes, copy number 5 (broad region; genes not listed).
- chr20:21,947,647–64,313,132, 1,037 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,455. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
